Gene-level copy-number profile of tumor specimen TCGA-02-0258-01A from TCGA case TCGA-02-0258, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.3 years (13,269 days).
Specimen TCGA-02-0258-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.d42a248b-77b1-448f-8520-8e791a2183c0.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,089 have no estimate.
https://portal.gdc.cancer.gov/files/313d0b88-846b-42fe-b16a-8dd4fa7b9ef2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 6,048; copy number 2: 44,548; copy number 3: 4,932.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0258-01): tumor purity 0.93, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:55,896,443–56,427,032, 6 genes: AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
